Gene-level copy-number profile of tumor specimen C3L-02515-03 from CPTAC case C3L-02515, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 68.6 years (25,050 days).
Specimen C3L-02515-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 67ef1671-9dce-47aa-aa7a-dce69963b34e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02515-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/ce75bb08-2878-47d9-93b0-3b4070791aeb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 7,413; copy number 2: 39,703; copy number 3: 11,078; copy number 4: 192; copy number 7: 10.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,850,283–196,918,713, 2 genes (within-gene range 0–3): BX248415.1, CFHR4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:21,452,197–21,743,630, 10 genes, copy number 7: AL158209.1, Metazoa_SRP, Y_RNA, MIR1915HG, MIR1915, SKIDA1, MLLT10, RNU6-306P, HNRNPRP1, RNU6-1141P.

Autosomal genes at a single copy (total copy number 1): 7,413. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
